FM case AD9443 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/f637ec8c-0013-4e5f-b2ca-4d0aee2b3f4e

Male, 54.4 years: Carcinoma, undifferentiated, NOS (ICD-O-3 8020/3) of the prostate gland; primary biopsied or resected from the prostate gland. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
